Gene-level copy-number profile of tumor specimen TCGA-KP-A3W3-01A from TCGA case TCGA-KP-A3W3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.0 years (26,310 days).
Specimen TCGA-KP-A3W3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.7f244e48-3db6-447d-b74a-d667f0c0ad4e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KP-A3W3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/580e8aee-6990-433d-8f2e-d02aa015ef8a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,300; copy number 2: 25,214; copy number 3: 16,461; copy number 4: 14,585; copy number 5: 976; copy number 6: 778; copy number 7: 488; copy number 8: 4; copy number 9: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KP-A3W3-01A-11D-A227-01): tumor purity 0.81, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,251 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,136,570–36,483,278, 15 genes, copy number 6: TRAPPC3, MAP7D1, RN7SL131P, THRAP3, UBE2V2P4, SH3D21, EVA1B, AL591845.1, STK40, LSM10, RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R.
- chr1:172,370,189–172,468,831, 2 genes, copy number 6 (within-gene range 4–6): PIGC, C1orf105.
- chr1:205,042,937–205,469,024, 17 genes, copy number 5 (within-gene range 4–5): CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT.
- chr2:88,364,695–90,190,681, 103 genes, copy number 6 (broad region; genes not listed).
- chr3:141,778,148–142,149,544, 9 genes, copy number 5 (within-gene range 4–5): GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1.
- chr4:57,720,035–60,038,586, 19 genes, copy number 5–8: AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:76,708,853–78,008,688, 26 genes, copy number 5: SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3.
- chr4:78,180,866–78,182,046, 1 gene, copy number 5: SERBP1P5.
- chr6:36,871,870–37,091,806, 7 genes, copy number 6 (within-gene range 4–6): C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2.
- chr6:41,789,896–41,895,361, 1 gene, copy number 6 (within-gene range 4–6): USP49.
- chr6:41,832,854–42,452,051, 17 genes, copy number 6 (within-gene range 4–6): AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1.
- chr6:49,834,257–65,707,226, 175 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:99,952,033–100,221,488, 27 genes, copy number 6 (within-gene range 4–6): AC004522.1, AZGP1, AC004522.4, AZGP1P1, AC004522.2, AC004522.5, ZKSCAN1, ZSCAN21, ZNF3, COPS6, MCM7, MIR25, MIR93, MIR106B, AP4M1, TAF6, AC073842.2, CNPY4, MBLAC1, AC073842.1, RPL7P60, LAMTOR4, MAP11, MIR4658, GAL3ST4, GPC2, STAG3.
- chr8:126,174,186–128,564,679, 37 genes, copy number 5: RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr10:11,742,366–12,043,170, 5 genes, copy number 5: ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P.
- chr11:60,515,392–62,423,195, 86 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr16:11,555–21,587,864, 787 genes, copy number 5 (broad region; genes not listed).
- chr19:29,287,011–32,485,895, 49 genes, copy number 6 (within-gene range 4–6): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3.
- chr20:30,278,906–63,891,545, 868 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
